Gene-level copy-number profile of tumor specimen TCGA-OR-A5LR-01A from TCGA case TCGA-OR-A5LR, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 30.8 years (11,261 days).
Specimen TCGA-OR-A5LR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.ce60e213-0a8a-4cb4-8707-18b19096a74f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/818ce32f-42ef-41c6-b86b-f092b1a2a0f4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 2: 44,837; copy number 4: 14,955.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LR-01A-11D-A29H-01): tumor purity 0.89, ploidy 1.22, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:106,088,122–106,293,808, 28 genes: IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12, IGHV3-13, IGHVIII-13-1, IGHV1-14, IGHV3-15, IGHVII-15-1, IGHV3-16, IGHVIII-16-1, IGHV1-17, SLC20A1P2, IGHV1-18, IGHV3-19, AC247036.1, IGHV3-20, IGHV3-21, IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
